Gene-level copy-number profile of tumor specimen HCM-CSHL-0063-C18-01A from HCMI case HCM-CSHL-0063-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIA; Tumor grade: G2; Age at diagnosis: 75.1 years (27,438 days).
Specimen HCM-CSHL-0063-C18-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file ff378732-530f-4561-ba8e-c77437d08d36.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0063-C18-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,712 have no estimate.
https://portal.gdc.cancer.gov/files/d31c2901-7a0c-4a78-aeda-c75f85d09e33

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 2; copy number 2: 14,425; copy number 3: 895; copy number 4: 39,429; copy number 5: 1,183; copy number 6: 1,279; copy number 7: 885; copy number 8: 806.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:33,577,502–33,707,213, 2 genes (within-gene range 0–4): AC142384.1, BMS1P8.
- chr16:34,013,394–34,120,677, 4 genes: AC133561.2, AC133561.4, AC133561.3, AC136932.1.
- chr17:74,770,529–74,776,367, 1 gene: NAT9.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 2. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
